Somatic mutation profile of tumor specimen TARGET-10-PARBYS-09A (aliquot TARGET-10-PARBYS-09A-01D) from TARGET case TARGET-10-PARBYS, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (889 days).
Specimen TARGET-10-PARBYS-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b11b99a-c6a3-4b44-83f1-cfeec8600984.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARBYS-10A (Blood Derived Normal), aliquot TARGET-10-PARBYS-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff11bb64-3928-4ebe-83ee-e9dfe992c7e8

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 2, Intron 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ENPEP | c.601G>A p.V201M | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs915463280, COSV54453232; called by muse, mutect2, varscan2
- IFT172 | c.2437G>A p.E813K | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1036729851; called by muse, mutect2, varscan2
- MYO3B | c.3436G>A p.E1146K | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0.005); catalogued as rs775746695; called by muse, mutect2, varscan2
- MYOG | c.63C>A p.N21K | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as rs1342072659; called by muse, mutect2, varscan2
- NCAN | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.435); catalogued as rs373800963; called by muse, mutect2, varscan2
- SLC4A10 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs759420527, COSV55768636; called by muse, mutect2, varscan2
- SRRM3 | c.1888C>T p.R630W | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.636); catalogued as rs868943449; called by muse, mutect2, varscan2
- EPHA5 | c.2957del p.F986Sfs*15 | Frame Shift Del (DEL) | VAF 49/167 reads (29%) | called by mutect2, pindel, varscan2
- PCDHA9 | c.2172G>A p.S724= | Silent (SNP) | VAF 34/71 reads (48%) | catalogued as rs781883944; called by muse, mutect2, varscan2
- ZFR2 | c.615C>T p.N205= | Silent (SNP) | VAF 15/40 reads (38%) | called by muse, mutect2
- MAP2K6 | c.366+66G>A | Intron (SNP) | VAF 23/63 reads (37%) | catalogued as rs1250337443; called by muse, mutect2, varscan2
- PHLDB1 | c.3874+62C>T | Intron (SNP) | VAF 5/21 reads (24%) | catalogued as rs1311449359, COSV61879258; called by muse, mutect2
